CCDI case PBBUDK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c883e962-d19c-4f4b-b821-d52e8b33b25c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,833 days).

Biospecimens (3 samples)
- Sample 0DHOGT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHOIZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHOJ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
